Somatic mutation profile of tumor specimen MP2PRT-PAUDSA-TMP1-A (aliquot MP2PRT-PAUDSA-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUDSA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 4.0 years (1,450 days).
Specimen MP2PRT-PAUDSA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74b0e280-806b-4db5-bc17-ac0cb7f5b74c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUDSA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUDSA-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0cdd002-b470-4cac-acce-e6ea2f2ae895

The open-access MAF lists 23 somatic variants for this specimen: 14 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 8, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 42/485 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- IGKV3-20 | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 254/371 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs185401231; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 182/507 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLAGL2 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 54/619 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.145); catalogued as rs1361375770; called by muse, mutect2
- PPP4R1 | c.2233C>G p.Q745E (on ENST00000400556 / NM_001042388.3; = p.Q728E on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/308 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1308948262; called by muse, mutect2
- RUSC2 | c.4466G>A p.R1489H | Missense Mutation (SNP) | VAF 36/778 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs777840197; called by muse, mutect2
- TLN2 | c.2359C>T p.H787Y | Missense Mutation (SNP) | VAF 91/634 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1228991832; called by muse, mutect2, varscan2
- AFF2 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 61/573 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- C4orf54 | c.2830T>C p.F944L | Missense Mutation (SNP) | VAF 150/432 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- CBLN1 | c.175A>C p.S59R | Missense Mutation (SNP) | VAF 21/708 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2
- NAA15 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 46/438 reads (11%) | called by muse, mutect2
- SH3TC2 | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 55/539 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC2A8 | c.803A>C p.Q268P | Missense Mutation (SNP) | VAF 18/586 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TAF2 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 42/534 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2
- FAM47C | c.1788G>A p.P596= | Silent (SNP) | VAF 26/468 reads (6%) | catalogued as rs1556332793, COSV100792257; called by muse, mutect2
- IGLV4-69 | chr22:22031471 del CA | Silent (DEL) | VAF 71/220 reads (32%) | called by pindel, varscan2*
- KCNH1 | c.1872C>A p.G624= (on ENST00000271751 / NM_172362.3; = p.G597= on NM_002238.4) | Silent (SNP) | VAF 195/505 reads (39%) | called by muse, mutect2, varscan2
- MRAP | c.264C>T p.L88= | Silent (SNP) | VAF 68/686 reads (10%) | called by muse, mutect2
- PCDHA8 | c.1365C>T p.F455= | Silent (SNP) | VAF 98/831 reads (12%) | catalogued as rs1554139276, COSV65334617; called by muse, mutect2, varscan2
- PCDHGA1 | c.1596G>C p.V532= | Silent (SNP) | VAF 45/405 reads (11%) | called by muse, mutect2, varscan2
- PDZRN3 | c.255G>A p.A85= | Silent (SNP) | VAF 59/757 reads (8%) | catalogued as COSV55192656; called by muse, mutect2
- TBC1D17 | c.1938C>T p.A646= | Silent (SNP) | VAF 25/490 reads (5%) | catalogued as COSV99681026; called by muse, mutect2
- HNRNPU | c.634+1188_634+1190delinsCC | Intron (DEL) | VAF 84/286 reads (29%) | called by pindel, varscan2*
